Somatic mutation profile of tumor specimen TCGA-HC-A4ZV-01A (aliquot TCGA-HC-A4ZV-01A-11D-A26M-08) from TCGA case TCGA-HC-A4ZV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.5 years (20,634 days).
Specimen TCGA-HC-A4ZV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 797d9113-cf53-4966-b6d3-0fabad3888ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A4ZV-10A (Blood Derived Normal), aliquot TCGA-HC-A4ZV-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/294e56fb-90c9-4fc5-8854-03a09e10dc4a

The open-access MAF lists 116 somatic variants for this specimen: 90 protein-altering or splice-affecting, 24 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 24, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 3, Intron 2, Frame Shift Ins 1, Nonstop Mutation 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABHD8 | c.995A>C p.N332T | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.417); catalogued as COSV56043885; called by muse, mutect2, varscan2
- AFF1 | c.412C>A p.P138T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as COSV57116442; called by mutect2, varscan2
- ANO3 | c.2813T>C p.V938A | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV56779648, COSV99880698; called by muse, mutect2, varscan2
- ANOS1 | c.755A>G p.D252G | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.198); catalogued as COSV52915677; called by muse, mutect2, varscan2
- AP1S3 | c.59A>T p.Y20F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV57509274; called by muse, mutect2, varscan2
- APPBP2 | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 48/144 reads (33%) | catalogued as COSV50025753; called by muse, mutect2, varscan2
- ARFGEF3 | c.5671C>T p.P1891S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs758993105, COSV52449749; called by muse, mutect2, varscan2
- ATM | c.8356G>A p.G2786S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1167044647, COSV53724907; called by muse, mutect2, varscan2
- AVL9 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.055); catalogued as COSV59463824; called by muse, mutect2, varscan2
- BCORL1 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54389206; called by muse, mutect2, varscan2
- BCORL1 | c.724G>C p.A242P | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV54389218; called by muse, mutect2, varscan2
- BPTF | c.7027A>G p.T2343A | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58830968; called by muse, mutect2, varscan2
- BRCA2 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs80359088, COSV66447803, COSV66461938; called by muse, mutect2, varscan2
- CA2 | c.322A>T p.T108S | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV53405655; called by muse, mutect2, varscan2
- CCDC9 | c.903-1G>A p.X301_splice | Splice Site (SNP) | VAF 9/35 reads (26%) | catalogued as COSV55719431; called by muse, mutect2, varscan2
- CD248 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV60935699; called by muse, mutect2, varscan2
- CEP76 | c.296-1G>T p.X99_splice | Splice Site (SNP) | VAF 18/37 reads (49%) | catalogued as COSV50865496; called by muse, mutect2, varscan2
- COMP | c.1147C>G p.Q383E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55873736; called by muse, mutect2, varscan2
- DALRD3 | c.1401C>A p.D467E (on ENST00000341949 / NM_001009996.3; = p.D300E on NM_018114.5) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as COSV58243829; called by muse, mutect2, varscan2
- DDX50 | c.1082C>A p.T361N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.263); catalogued as COSV65291651; called by muse, mutect2, varscan2
- DIDO1 | c.3707A>G p.Q1236R | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs754990907, COSV56613255; called by muse, mutect2, varscan2
- DMBX1 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV63601629; called by muse, mutect2
- DNM1L | c.1508A>T p.D503V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as rs1215143262, COSV56771982; called by muse, mutect2, varscan2
- DYNLT1 | c.284T>G p.V95G | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV65560092; called by muse, mutect2, varscan2
- EMILIN2 | c.2214G>C p.W738C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54420909, COSV99598207; called by muse, mutect2, varscan2
- F5 | c.6593C>T p.S2198F | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63120221; called by muse, mutect2, varscan2
- FAT3 | c.959G>A p.W320* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV53073653, COSV53187243; called by mutect2, varscan2
- FBLN5 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.705); catalogued as rs760345539, COSV50902040; called by muse, mutect2, varscan2
- FOXB2 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.003); catalogued as COSV65022372; called by muse, mutect2, varscan2
- FOXD2 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58303394; called by muse, mutect2, varscan2
- GPR55 | c.587T>C p.I196T | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.029); catalogued as COSV67406976; called by muse, mutect2, varscan2
- GRIN2A | c.1417T>A p.F473I | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58019155; called by muse, mutect2, varscan2
- HK2 | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 75/207 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51873048; called by muse, mutect2, varscan2
- IZUMO1R | c.317G>A p.W106* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV60622091; called by muse, mutect2, varscan2
- KDM2A | c.2455C>A p.L819M | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as COSV58188361; called by muse, mutect2, varscan2
- KIF19 | c.2645A>C p.E882A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1336165692, COSV100738993; called by mutect2, varscan2
- KIF5C | c.890G>A p.R297K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV68479733, COSV68480204; called by muse, mutect2, varscan2
- KLHL38 | c.346T>C p.F116L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs773031569, COSV58085886; called by muse, mutect2, varscan2
- KMT2C | c.1966G>A p.V656I | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs750959766, COSV51282732; called by muse, mutect2, varscan2
- KRTAP10-4 | c.377T>G p.V126G | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.141); catalogued as COSV59951128; called by muse, mutect2
- LRP4 | c.3874A>C p.N1292H | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.05); catalogued as COSV66133871; called by muse, mutect2, varscan2
- LSM14B | c.1148G>T p.G383V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.723); catalogued as COSV53378252; called by muse, mutect2, varscan2
- ME3 | c.1111T>A p.S371T | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.092); catalogued as COSV62770690; called by muse, mutect2, varscan2
- MME | c.1765G>T p.G589C | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64705908; called by muse, mutect2, varscan2
- MRNIP | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.076); catalogued as rs1289693891, COSV52971678; called by muse, mutect2, varscan2
- MRPL40 | c.360G>T p.K120N | Missense Mutation (SNP) | VAF 63/184 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.493); catalogued as COSV54271962; called by muse, mutect2, varscan2
- MRTO4 | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.649); catalogued as COSV57672998; called by muse, mutect2, varscan2
- MYO3A | c.4778C>G p.A1593G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV52150136; called by muse, mutect2, varscan2
- PADI1 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as rs367912075, COSV64933888; called by muse, mutect2
- PADI4 | c.756G>C p.E252D | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV64922998; called by muse, mutect2, varscan2
- PCDH10 | c.592C>T p.R198C | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as COSV52087165, COSV99994319; called by muse, mutect2, varscan2
- PCP4 | c.189G>C p.*63Yext*27 | Nonstop Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV60786021; called by muse, mutect2, varscan2
- PIGR | c.146G>A p.R49Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs780994524, COSV62903211; called by muse, mutect2, varscan2
- PRMT1 | c.515C>G p.S172C | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV67159112, COSV67159957; called by muse, mutect2
- PSMC5 | c.989A>T p.K330M | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV56737836; called by muse, mutect2, varscan2
- PSMG3 | c.193A>G p.K65E | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as rs763291710, COSV52920386; called by muse, mutect2, varscan2
- PZP | c.2332C>A p.L778M | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as COSV54353981, COSV54368495; called by muse, mutect2, varscan2
- RALYL | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as COSV72817339; called by muse, mutect2, varscan2
- RELN | c.10133A>T p.Q3378L | Missense Mutation (SNP) | VAF 46/211 reads (22%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.725); catalogued as COSV58984891; called by muse, mutect2, varscan2
- RNF149 | c.1187G>T p.G396V | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV54862778; called by muse, mutect2, varscan2
- RNF8 | c.815A>G p.N272S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV57720527; called by muse, mutect2, varscan2
- RPS6KA5 | c.2323A>T p.T775S | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV56219254; called by muse, mutect2, varscan2
- SAXO1 | c.418A>G p.K140E | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.341); catalogued as COSV65868360; called by muse, mutect2, varscan2
- SNX31 | c.740T>A p.L247* | Nonsense Mutation (SNP) | VAF 17/137 reads (12%) | catalogued as COSV61261564; called by muse, mutect2, varscan2
- SPEG | c.3425A>G p.H1142R | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56662601; called by muse, mutect2, varscan2
- SRCAP | c.8479G>A p.A2827T | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as COSV52667210; called by muse, mutect2, varscan2
- SSH2 | c.584A>C p.N195T | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV52166155; called by muse, mutect2, varscan2
- STOX2 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.12); catalogued as rs756466070, COSV100408228, COSV57848534; called by muse, mutect2, varscan2
- TECPR1 | c.2215G>A p.D739N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs777645927, COSV65782511; called by muse, mutect2, varscan2
- TEK | c.3035A>G p.Y1012C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66227322; called by muse, mutect2, varscan2
- THYN1 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.734); catalogued as COSV55538892; called by muse, mutect2, varscan2
- TTC1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV51463680; called by muse, mutect2, varscan2
- TTLL3 | c.744+1G>A p.X248_splice | Splice Site (SNP) | VAF 5/13 reads (38%) | catalogued as COSV59613395; called by muse, mutect2
- UACA | c.3737A>T p.K1246I | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV59853157; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2857A>T p.S953C | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV54434318; called by muse, mutect2, varscan2
- WASF2 | c.358G>C p.V120L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV71004752; called by muse, mutect2, varscan2
- WNK1 | c.638G>A p.G213E | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV60025222; called by muse, mutect2, varscan2
- ZFP28 | c.899-1G>C p.X300_splice | Splice Site (SNP) | VAF 15/54 reads (28%) | catalogued as COSV56734476; called by muse, mutect2, varscan2
- ZNF721 | c.2200A>G p.I734V (on ENST00000338977; = p.I746V on NM_133474.4) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV59088816; called by muse, mutect2, varscan2
- ZNF770 | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62543833; called by muse, mutect2, varscan2
- ZSWIM3 | c.1375A>T p.I459F | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV54845023; called by muse, mutect2, varscan2
- ACSS2 | c.518_536del p.L173Hfs*46 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | called by mutect2, pindel
- CYFIP1 | c.539G>T p.S180I | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.273); called by mutect2, varscan2
- GAS2L2 | c.927G>A p.M309I | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LRRC37A2 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by mutect2, varscan2
- RBMS2 | c.21del p.R8Gfs*46 | Frame Shift Del (DEL) | VAF 24/79 reads (30%) | called by mutect2, pindel, varscan2
- SYPL1 | c.232_233delinsGAA p.F78Efs*9 | Frame Shift Ins (INS) | VAF 20/100 reads (20%) | called by pindel, varscan2*
- TENM1 | c.2116_2130del p.S706_C710del | In Frame Del (DEL) | VAF 8/12 reads (67%) | called by mutect2, varscan2
- ZDHHC14 | c.121del p.E41Rfs*16 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- ZNF569 | c.1671_1680delinsTTAAG p.K557Nfs*2 | Nonsense Mutation (DEL) | VAF 18/67 reads (27%) | called by pindel, varscan2*
- ABCC3 | c.1152G>T p.G384= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV53316954; called by muse, mutect2, varscan2
- ADAMTS10 | c.312G>T p.V104= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV54351785, COSV54357613; called by muse, mutect2, varscan2
- ADGRE2 | c.15C>G p.V5= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV59691569; called by muse, mutect2, varscan2
- ATR | c.6186T>A p.G2062= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as COSV63383614; called by muse, mutect2
- DPH5 | c.180A>G p.E60= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV59858941; called by muse, mutect2, varscan2
- F5 | c.6594C>T p.S2198= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV63120210; called by muse, mutect2, varscan2
- FASTKD5 | c.1653G>A p.K551= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53904080; called by muse, mutect2, varscan2
- MN1 | c.3270C>T p.G1090= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs147753551, COSV56555863; called by muse, mutect2, varscan2
- MUC5B | c.8802G>T p.V2934= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV101500117; called by muse, mutect2, varscan2
- MYSM1 | c.867T>A p.L289= | Silent (SNP) | VAF 32/53 reads (60%) | catalogued as COSV68976898; called by muse, mutect2, varscan2
- PCDHGA8 | c.720G>A p.P240= | Silent (SNP) | VAF 28/98 reads (29%) | catalogued as COSV53895150, COSV99530055; called by muse, mutect2, varscan2
- PEAR1 | c.663C>T p.S221= | Silent (SNP) | VAF 126/254 reads (50%) | catalogued as COSV52770656; called by muse, mutect2, varscan2
- PRR16 | c.903T>C p.T301= (on ENST00000407149 / NM_001300783.2; = p.T278= on NM_016644.2) | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV65394498; called by muse, mutect2, varscan2
- SAGE1 | c.1333A>C p.R445= | Silent (SNP) | VAF 34/53 reads (64%) | catalogued as COSV61011501; called by muse, mutect2, varscan2
- SIGLEC9 | c.240T>G p.A80= | Silent (SNP) | VAF 31/110 reads (28%) | catalogued as COSV51582446; called by muse, mutect2, varscan2
- SLCO1B1 | c.2070T>C p.H690= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV57006903; called by muse, mutect2, varscan2
- TAAR5 | c.327G>A p.L109= | Silent (SNP) | VAF 28/109 reads (26%) | catalogued as COSV57798425; called by muse, mutect2, varscan2
- TACC2 | c.603G>A p.S201= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1159256265, COSV57745522; called by muse, mutect2, varscan2
- TENM3 | c.7041C>A p.T2347= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as rs750273630, COSV69298868; called by muse, mutect2, varscan2
- TRAV18 | c.150T>G p.T50= | Silent (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- TRPC4 | c.2115A>G p.Q705= (on ENST00000379705 / NM_016179.4; = p.Q710= on NM_003306.3) | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as COSV58989717; called by muse, mutect2, varscan2
- TTC6 | c.558C>T p.Y186= (on ENST00000267368; = p.Y1552= on NM_001310135.3) | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs149048537; called by muse, mutect2, varscan2
- TTC7A | c.1791T>A p.P597= | Silent (SNP) | VAF 27/85 reads (32%) | catalogued as COSV55408294; called by muse, mutect2, varscan2
- ZBTB46 | c.1386G>A p.K462= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV55506550; called by muse, mutect2, varscan2
- CACNB4 | c.148-90302G>T | Intron (SNP) | VAF 5/16 reads (31%) | catalogued as COSV52388410; called by muse, mutect2, varscan2
- MACF1 | c.15832-10605G>T | Intron (SNP) | VAF 11/28 reads (39%) | catalogued as COSV57104738; called by muse, mutect2, varscan2
